Gene-level copy-number profile of tumor specimen TCGA-NH-A50U-01A from TCGA case TCGA-NH-A50U, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage IVA; Age at diagnosis: 42.3 years (15,450 days).
Specimen TCGA-NH-A50U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.6de86451-aef6-40a0-92b1-06e7fc5f9d12.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NH-A50U-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (sample pair TCGA-NH-A50U-01A|TCGA-NH-A50U-10B); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/915088f4-82f4-4c70-90d1-ac08f6996d89

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 1,638; copy number 2: 26,600; copy number 3: 22,009; copy number 4: 9,404; copy number 6: 138; copy number 8: 19; copy number 9: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NH-A50U-01A-33D-A36W-01): tumor purity 0.83, ploidy 2.77, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr15:67,063,763–67,195,169, 2 genes (within-gene range 0–2): SMAD3, AC012568.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 167 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:3,071,532–4,445,614, 31 genes, copy number 6: AC125807.1, TSPAN9, Metazoa_SRP, TSPAN9-IT1, AC005912.2, AC005912.1, AC005865.1, AC005865.2, LINC02827, LINC02417, PRMT8, AC005908.2, AC005908.1, THCAT155, CRACR2A, AC005831.1, RNU6-174P, AC006207.1, PARP11, OTUD4P1, PARP11-AS1, AC084375.1, HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6.
- chr12:5,290,480–5,406,651, 4 genes, copy number 6: AC006206.2, AC006206.1, AC007848.2, AC007848.1.
- chr12:19,129,752–21,604,847, 36 genes, copy number 6–8 (within-gene range 2–8): PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, AC126468.1, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2.
- chr12:22,625,075–27,824,382, 94 genes, copy number 6–9 (within-gene range 4–9) (broad region; genes not listed).
- chr12:28,505,394–28,565,141, 2 genes, copy number 6: RNA5SP355, AC084754.1.

Autosomal genes at a single copy (total copy number 1): 1,638. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
